Somatic mutation profile of tumor specimen ALCH-ACWK-TTP1-A (aliquot ALCH-ACWK-TTP1-A-1-0-D-A501-36) from ALCHEMIST case ALCH-ACWK, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 53.2 years (19,437 days).
Specimen ALCH-ACWK-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ce0e1b90-d4a0-42c9-8aa0-124f15bba009.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ACWK-NB1-A (Blood Derived Normal), aliquot ALCH-ACWK-NB1-A-1-0-D-A501-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/94c6c5e5-d75a-459c-9f4b-16cf78d86578

The open-access MAF lists 60 somatic variants for this specimen: 36 protein-altering or splice-affecting, 13 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 13, Intron 5, Frame Shift Del 3, 3'UTR 3, Splice Region 2, RNA 2, Splice Site 1, Nonsense Mutation 1, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALDH16A1 | c.977G>A p.R326Q | Missense Mutation (SNP) | VAF 43/250 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778552511; called by muse, mutect2, varscan2
- ANKS4B | c.1072G>C p.E358Q | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV61139047; called by muse, mutect2
- DEAF1 | c.69_98del p.A24_A33del | In Frame Del (DEL) | VAF 10/137 reads (7%) | catalogued as rs754135731; called by muse*, mutect2
- EXD3 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as rs1315399586; called by muse, mutect2
- FBXL7 | c.1081G>A p.G361S | Missense Mutation (SNP) | VAF 21/317 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs375930592; called by muse, mutect2
- FOXO6 | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated, low confidence (0.27); catalogued as rs1183749300; called by muse, mutect2
- RNF166 | c.649-4C>T | Splice Region (SNP) | VAF 8/156 reads (5%) | catalogued as rs1182985283; called by muse, mutect2
- SDK2 | c.6118G>A p.E2040K | Missense Mutation (SNP) | VAF 23/220 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV101168427; called by muse, mutect2, varscan2
- SLC27A5 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.1); catalogued as rs748370633; called by muse, mutect2, varscan2
- TERT | c.1573+6G>T | Splice Region (SNP) | VAF 38/154 reads (25%) | catalogued as rs1561213199; called by muse, mutect2, varscan2
- ZFHX4 | c.9230C>T p.T3077M | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.172); catalogued as rs377249680; called by muse, mutect2
- ANKRD6 | c.687del p.G230Efs*45 | Frame Shift Del (DEL) | VAF 44/219 reads (20%) | called by mutect2, pindel, varscan2
- AP1B1 | c.1946C>G p.S649C | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.371); called by muse, mutect2
- CCDC168 | c.7265C>A p.S2422Y | Missense Mutation (SNP) | VAF 81/201 reads (40%) | SIFT tolerated (1); PolyPhen probably damaging (0.953); called by mutect2, varscan2
- CDCA2 | c.1365+1del p.X455_splice | Splice Site (DEL) | VAF 38/151 reads (25%) | called by mutect2, pindel, varscan2
- CHD2 | c.2678A>G p.N893S | Missense Mutation (SNP) | VAF 62/288 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- COL4A6 | c.332A>G p.H111R | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- CPSF1 | c.1462G>T p.E488* | Nonsense Mutation (SNP) | VAF 26/176 reads (15%) | called by muse, varscan2
- CYLC1 | c.1095G>T p.K365N | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- EDEM2 | c.1099_1111del p.Y367Qfs*20 | Frame Shift Del (DEL) | VAF 24/108 reads (22%) | called by mutect2, pindel, varscan2
- EPOR | c.1213T>A p.S405T | Missense Mutation (SNP) | VAF 96/543 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- FBXO41 | c.2294G>A p.R765K | Missense Mutation (SNP) | VAF 10/135 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.969); called by muse, mutect2
- GGCX | c.343A>T p.M115L | Missense Mutation (SNP) | VAF 63/331 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- GLB1L3 | c.1630A>T p.I544F | Missense Mutation (SNP) | VAF 159/473 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- GNAT2 | c.138G>C p.K46N | Missense Mutation (SNP) | VAF 31/620 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GTF3C1 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 30/173 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- HMGXB4 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 19/176 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- HSPA1L | c.73C>A p.H25N | Missense Mutation (SNP) | VAF 16/331 reads (5%) | SIFT tolerated, low confidence (0.4); PolyPhen possibly damaging (0.587); called by muse, mutect2
- LAMC2 | c.1469G>T p.G490V | Missense Mutation (SNP) | VAF 20/270 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LCP2 | c.1343G>C p.R448T | Missense Mutation (SNP) | VAF 25/260 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LRBA | c.4870C>T p.H1624Y | Missense Mutation (SNP) | VAF 15/421 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2
- MAGEA12 | c.638G>A p.G213D | Missense Mutation (SNP) | VAF 103/659 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- NEK5 | c.84G>T p.K28N | Missense Mutation (SNP) | VAF 25/213 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SEC16B | c.1016T>C p.V339A | Missense Mutation (SNP) | VAF 145/536 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- TCF4 | c.58C>A p.L20M | Missense Mutation (SNP) | VAF 120/503 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRIM44 | c.519_520del p.R173Sfs*12 | Frame Shift Del (DEL) | VAF 98/570 reads (17%) | called by pindel, varscan2
- ALK | c.3423C>T p.D1141= | Silent (SNP) | VAF 67/317 reads (21%) | catalogued as rs747239082; called by muse, mutect2, varscan2
- AQP10 | c.402G>C p.L134= | Silent (SNP) | VAF 26/310 reads (8%) | catalogued as COSV100270121, COSV100270310; called by muse, mutect2
- CCDC168 | c.10384T>C p.L3462= | Silent (SNP) | VAF 18/332 reads (5%) | called by muse, mutect2
- EIF2B5 | c.405C>T p.L135= | Silent (SNP) | VAF 24/503 reads (5%) | called by muse, mutect2
- FOXP1 | c.1212T>G p.P404= | Silent (SNP) | VAF 44/232 reads (19%) | called by muse, mutect2, varscan2
- FRMD6 | c.990C>G p.V330= (on ENST00000344768 / NM_001267046.2; = p.V322= on NM_152330.4) | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as rs369250709; called by muse, mutect2, varscan2
- H1-5 | c.594G>T p.P198= | Silent (SNP) | VAF 24/191 reads (13%) | catalogued as COSV58898866; called by muse, mutect2, varscan2
- KIAA1614 | c.636G>A p.P212= | Silent (SNP) | VAF 21/152 reads (14%) | catalogued as rs559560066, COSV62553199; called by muse, mutect2
- MPV17 | c.523C>A p.R175= | Silent (SNP) | VAF 51/411 reads (12%) | catalogued as rs374686068; called by muse, mutect2, varscan2
- PTCHD3 | c.552C>T p.F184= | Silent (SNP) | VAF 22/145 reads (15%) | catalogued as rs764224948, COSV71256611; called by muse, mutect2, varscan2
- PTPRN2 | c.2367G>A p.L789= | Silent (SNP) | VAF 47/479 reads (10%) | called by muse, mutect2
- TTLL5 | c.3264G>A p.P1088= | Silent (SNP) | VAF 20/98 reads (20%) | catalogued as rs376141983, COSV54030154; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZNF84 | c.108G>A p.V36= | Silent (SNP) | VAF 11/260 reads (4%) | catalogued as rs1458541672; called by muse, mutect2
- BEX2 | c.-81-175C>T | Intron (SNP) | VAF 32/238 reads (13%) | called by muse, mutect2, varscan2
- BRWD3 | c.2231+31dup | Intron (INS) | VAF 22/182 reads (12%) | called by mutect2, varscan2
- CCDC83 | chr11:85853472 T>G | 5'Flank (SNP) | VAF 18/49 reads (37%) | called by muse, mutect2, varscan2
- LIMS2 | c.360-433G>A | Intron (SNP) | VAF 14/375 reads (4%) | catalogued as rs1165431718; called by muse, mutect2
- PEX16 | c.*48del | 3'UTR (DEL) | VAF 37/365 reads (10%) | called by mutect2, pindel, varscan2
- ROBO2 | c.3761-2382G>C | Intron (SNP) | VAF 22/120 reads (18%) | called by muse, mutect2
- SCN4B | c.*397G>A | 3'UTR (SNP) | VAF 117/774 reads (15%) | called by muse, mutect2, varscan2
- SRSF10 | c.438-45C>A | Intron (SNP) | VAF 26/173 reads (15%) | called by muse, varscan2
- TUBBP5 | n.1427C>T | RNA (SNP) | VAF 14/84 reads (17%) | catalogued as rs189844666; called by muse, mutect2
- XIST | n.9685C>T | RNA (SNP) | VAF 24/737 reads (3%) | called by muse, mutect2
- ZNF99 | c.*1043C>T | 3'UTR (SNP) | VAF 31/214 reads (14%) | catalogued as rs112264342; called by muse, mutect2, varscan2
